Gene-level copy-number profile of tumor specimen TCGA-08-0354-01A from TCGA case TCGA-08-0354, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.6 years (19,199 days).
Specimen TCGA-08-0354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b2e40210-528b-47e4-b0b2-b6af2f1dae7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-08-0354-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/11a8ec57-2b4b-4953-9ba4-4e0a81c83461

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 4; copy number 2: 8,153; copy number 4: 48,114; copy number 5: 6; copy number 6: 448; copy number 8: 2,991; copy number 12: 20; copy number 26: 35; copy number 50: 12; copy number 53: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0354-01): tumor purity 0.76, ploidy 2, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,440,439–22,214,672, 24 genes: IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 78 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:242,882,066–245,709,432, 55 genes, copy number 12–26: AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5, DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8, AC104462.2, AC104462.1.
- chr7:54,542,325–55,646,951, 23 genes, copy number 50–53 (within-gene range 10–53): VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
